Gene-level copy-number profile of tumor specimen TCGA-IC-A6RE-01A from TCGA case TCGA-IC-A6RE, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 59.2 years (21,640 days).
Specimen TCGA-IC-A6RE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.5a4d2823-e971-4815-974a-afaea43f45d0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IC-A6RE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c8c643de-d908-4d4e-8296-8b8280c3f92b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 3,542; copy number 2: 40,039; copy number 3: 12,739; copy number 4: 2,446; copy number 5: 327; copy number 6: 303; copy number 9: 49; copy number 11: 188; copy number 14: 25; copy number 17: 72; copy number 31: 5; copy number 32: 6; copy number 35: 34; copy number 36: 15; copy number 48: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IC-A6RE-01A-11D-A33D-01): tumor purity 0.54, ploidy 2.24, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:4,749,192–4,887,293, 3 genes: EGOT, AC018816.2, AC018816.1.
- chr7:134,284,500–134,350,791, 3 genes: AC008154.2, SLC35B4, AC008154.1.
- chr20:14,884,250–14,935,363, 2 genes: MACROD2-AS1, AL138808.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,038 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:85,442,495–91,931,714, 213 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr7:78,017,055–79,453,667, 1 gene, copy number 5 (within-gene range 4–5): MAGI2.
- chr7:78,939,850–89,754,726, 96 genes, copy number 5 (broad region; genes not listed).
- chr7:91,311,368–91,515,427, 1 gene, copy number 36 (within-gene range 4–36): AC079760.2.
- chr7:91,380,778–102,679,295, 319 genes, copy number 11–48 (within-gene range 2–48) (broad region; genes not listed).
- chr17:33,935,437–34,156,000, 1 gene, copy number 5 (within-gene range 3–5): AC004147.4.
- chr17:34,080,882–34,482,148, 15 genes, copy number 5: AC004147.1, AC004147.5, RNA5SP438, AC004147.3, AC004147.2, LINC01989, AC005549.1, CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1, AC011193.1.
- chr17:38,765,689–44,221,626, 343 genes, copy number 6–9 (within-gene range 2–9) (broad region; genes not listed).
- chr17:52,390,515–52,987,652, 3 genes, copy number 5–9: LINC01982, LINC02089, LINC02876.
- chr19:28,790,812–31,349,436, 46 genes, copy number 6–35 (within-gene range 2–35): MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791.

Autosomal genes at a single copy (total copy number 1): 3,542. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
